Gene-level copy-number profile of tumor specimen 1105263 from CPTAC case C298152, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105263: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file af1f2987-6ca7-4a73-858e-85633c292353.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105208 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,736 have no estimate.
https://portal.gdc.cancer.gov/files/d28bb0da-1cb0-4ea4-a01d-9cab5c8e97fb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 347; copy number 1: 4,914; copy number 2: 51,039; copy number 3: 2,320; copy number 4: 27; copy number 7: 7; copy number 8: 31; copy number 9: 28; copy number 10: 3; copy number 11: 1; copy number 16: 2; copy number 19: 7; copy number 20: 8; copy number 21: 2; copy number 22: 2; copy number 24: 4; copy number 25: 20; copy number 28: 33; copy number 32: 4; copy number 38: 12; copy number 48: 33; copy number 60: 26; copy number 107: 5; copy number 108: 3; copy number 112: 9.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:80,233,664–80,254,121, 3 genes: AL513174.1, EIF5AP4, AL359195.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 240 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:242,671,140–244,451,909, 33 genes, copy number 48: AC099785.1, RSL24D1P4, AL445675.1, AL445675.2, AL603825.1, AL606534.3, SEPTIN14P21, CICP21, AL606534.4, LINC01347, RNU6-747P, CEP170, AL606534.1, AL606534.2, SDCCAG8, FCF1P7, MIR4677, AKT3, AL591721.1, FABP7P1, AL662889.1, AKT3-IT1, LINC02774, ZBTB18, AL590483.3, AL590483.1, AL590483.4, RN7SL148P, AL590483.2, C1orf100, AL645465.1, TGIF2P1, ADSS2.
- chr7:47,275,154–47,582,558, 1 gene, copy number 38: TNS3.
- chr7:53,490,148–55,713,252, 37 genes, copy number 38–60: RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P.
- chr12:57,253,762–57,984,761, 51 genes, copy number 8–28 (within-gene range 1–28): R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:58,544,124–59,450,772, 10 genes, copy number 9–16: AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P.
- chr12:60,092,864–60,419,293, 6 genes, copy number 9: AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2.
- chr12:61,600,067–62,417,431, 9 genes, copy number 7–9 (within-gene range 1–87): DUX4L52, TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125.
- chr12:62,393,607–62,393,880, 1 gene, copy number 8 (within-gene range 8–87): Metazoa_SRP.
- chr12:62,601,751–63,006,902, 13 genes, copy number 20–107: LINC01465, AC048341.1, MIRLET7I, AC048341.2, PPM1H, RPL32P26, GAPDHP44, RNU1-83P, Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1.
- chr12:63,271,404–63,360,037, 2 genes, copy number 7–20: HNRNPA1P69, AC026116.1.
- chr12:64,222,337–64,397,065, 1 gene, copy number 8 (within-gene range 1–8): AC012158.1.
- chr12:64,264,762–64,507,329, 9 genes, copy number 8–19 (within-gene range 1–19): C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1, XPOT, AC135279.2, AC135279.3, TBK1, AC136977.1.
- chr12:64,759,484–65,491,430, 16 genes, copy number 8–21 (within-gene range 1–21): TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60.
- chr12:65,758,020–67,352,039, 29 genes, copy number 8–108: RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, MRPL40P1.
- chr12:67,929,235–68,253,604, 9 genes, copy number 8–25: LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22.
- chr12:68,674,371–68,971,570, 13 genes, copy number 32–112 (within-gene range 1–112): AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5.

Autosomal genes at a single copy (total copy number 1): 2,431. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
